Somatic mutation profile of tumor specimen TARGET-10-PARDRI-09A (aliquot TARGET-10-PARDRI-09A-01D) from TARGET case TARGET-10-PARDRI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.9 years (3,624 days).
Specimen TARGET-10-PARDRI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5a6e9fa-ce1c-4b68-ab62-511c5a2d417c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDRI-10A (Blood Derived Normal), aliquot TARGET-10-PARDRI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd3d1721-213f-41ac-970f-ea93bf1aeab1

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 3, Frame Shift Ins 1, Frame Shift Del 1, RNA 1, Splice Region 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS1 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs373846648; called by muse, mutect2, varscan2
- BSND | c.300G>C p.R100S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.994); catalogued as COSV64870744; called by muse, mutect2, varscan2
- CAVIN2 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs760185073, COSV100414406; called by muse, mutect2, varscan2
- GNAS | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.031); catalogued as rs776193516; called by muse, mutect2, varscan2
- KRTAP4-11 | c.107G>C p.R36T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV101195027; called by muse, varscan2
- PCBP3 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs1569511409; called by muse, mutect2, varscan2
- SIDT2 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.18); catalogued as rs764739203; called by muse, mutect2, varscan2
- THNSL1 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64479677; called by muse, mutect2, varscan2
- DPF1 | c.960+1G>A p.X320_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- EBF2 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FER1L6 | c.2834T>C p.L945P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.929); called by muse, mutect2
- KLRF1 | c.546G>C p.M182I | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LMAN1L | c.331-6C>A | Splice Region (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- NELL1 | c.22G>T p.V8F | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated, low confidence (0.77); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SCN9A | c.1457del p.K486Rfs*79 | Frame Shift Del (DEL) | VAF 8/91 reads (9%) | called by mutect2, pindel
- SETDB1 | c.1424+1dup | Frame Shift Ins (INS) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- IFT140 | c.822C>T p.S274= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs200604057, COSV101276704; called by muse, mutect2, varscan2
- TOGARAM2 | c.1464G>A p.P488= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs764461123, COSV65420550; called by muse, mutect2, varscan2
- VIPR2 | c.315C>T p.F105= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs186398445, COSV51103495; called by muse, mutect2, varscan2
- BCLAF3 | c.-10G>A | 5'UTR (SNP) | VAF 35/51 reads (69%) | catalogued as rs749016386; called by muse, mutect2, varscan2
- C9orf163 | n.1432A>C | RNA (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- DCC | c.3163+177A>G | Intron (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2
- GUCY1A2 | c.1207-13679T>C | Intron (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- MYEF2 | c.986-112T>G | Intron (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
